Somatic mutation profile of tumor specimen TARGET-30-PASZST-01A (aliquot TARGET-30-PASZST-01A-01D) from TARGET case TARGET-30-PASZST, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 2.5 years (923 days).
Specimen TARGET-30-PASZST-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e08c1389-c5bc-41e3-85f6-8768268a8cca.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASZST-10A (Blood Derived Normal), aliquot TARGET-30-PASZST-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4869f55d-56c7-46ca-8b4b-3768d5ca5c8d

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRIF1 | c.650C>T p.T217I | Missense Mutation (SNP) | VAF 56/259 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as COSV63898757; called by muse, mutect2, varscan2
- SIX1 | c.*1070T>A | 3'UTR (SNP) | VAF 63/141 reads (45%) | catalogued as COSV55961649; called by muse, mutect2, varscan2
